CCDI case PBBUUR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/17fe3880-4deb-4392-9ff6-cfb2824f4bc7

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; Tissue or organ of origin: Body of pancreas; Age at diagnosis: 9.8 years (3,588 days).

Biospecimens (3 samples)
- Sample 0DIY5V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIY62: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIY69: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
